Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMQ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMQ-01A (Primary Tumor).

[page 1 of 6]
DIAGNOSIS:

ANTERIOR EXENTERATION WITH T-POUCH:

RIGHT URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

URETHRAL MARGIN (C):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETHRAL AND PERIURETHRAL TISSUE

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

UTERUS, CERVIX, OVARIES AND BLADDER (D):

BLADDER:

- INVASIVE POORLY DIFFERENTIATED PAPILLARY UROTHELIAL CARCINOMA OF RIGHT LATERAL BLADDER WALL (2.5 X 1.0 CM) AND DOME (4.0 X 3.0 X 1.0 CM), GRADES 3 & 4/4,

INVOLVING LAMINA PROPRIA (RIGHT LATERAL WALL) AND SUPERFICIAL MUSCULARIS PROPRIA [SEE COMMENT]

- UROTHELIAL CARCINOMA IN SITU (FLAT LESION) ASSOCIATED WITH INVASIVE CARCINOMA IN RIGHT LATERAL BLADDER WALL

- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED

- DIVERTICULUM, BLADDER DOME

- RANDOM BLADDER MUCOSA, CHRONIC INFLAMMATION WITH ASSOCIATED REACTIVE UROTHELIAL CHANGES

- BLADDER NECK / TRIGONE, SQUAMOUS METAPLASIA

- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY

UTERUS, CERVIX:

- CERVIX, CHRONIC INFLAMMATION WITH SQUAMOUS METAPLASIA

- ENDOMETRIUM, INACTIVE WITH BENIGN FIBROTIC SESSILE ENDOMETRIAL POLYP

- MYOMETRIUM, NO SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY

- SEROSA, NO SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY

- BILATERAL OVARIES, BENIGN PHYSIOLOGICAL CHANGES AND SIMPLE EPITHELIAL INCLUSION CYSTS

- LEFT FALLOPIAN TUBE, BENIGN PARATUBAL CYST

- RIGHT FALLOPIAN TUBE, NO SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY

- NO EVIDENCE OF DYSPLASIA, ATYPIA OR MALIGNANCY IDENTIFIED

RIGHT COMMON ILIAC LYMPH NODES (E):

- BENIGN FIBROADIPOSE TISSUE

- NO LYMPHOID TISSUE OR MALIGNANCY IDENTIFIED (0/0) [TOTALLY SUBMITTED]

LEFT PARA AORTIC LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

ICD-O-3

Carcinoma, urothelial, papillary

Site: Bladder, lateral wall

8/30/3

QW 3/26/14

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

RIGHT PARA AORTIC LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN 12 LYMPH NODES EXAMINED (0/12)

LEFT COMMON ILIAC LYMPH NODES (H):

- NO MALIGNANCY IDENTIFIED IN 11 LYMPH NODES EXAMINED (0/11)

RIGHT LYMPH NODE OF CLOQUET (I):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (K):

- NO MALIGNANCY IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

LEFT EXTERNAL ILIAC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

LEFT LYMPH NODE OF CLOQUET (M):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (N):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT PRESACRAL LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT PRESACRAL LYMPH NODES (P):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

PRESACRAL LYMPH NODES (Q):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT URETER (S):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: NO TUMOR IDENTIFIED IN 67 LYMPH NODES EXAMINED (0/67)

PATHOLOGIC TNM STAGE: pTis,T2aN0MX

Electronically signed by
Verified:

COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay by immunohistology, results of which will be issued in an addendum.

SPECIMEN SOURCE:

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

- A: "Right ureter f/s"
- B: "Left ureter f/s"
- C: "Urethral margin"
- D: "Uterus, cervix, ovaries, bladder"
- E: "Right common iliac lymph node"
- F: "Left para aortic L.N."
- G: "Right para caval L.N."
- H: "Left common iliac L.N."
- I: "Right L.N. of cloquet"
- J: "Right external iliac L.N."
- K: "Right obturator hypogastric L.N."
- L: "Left external iliac L.N."
- M: "Left L.N. of cloquet"
- N: "Left obturator/hypogastric L.N."
- O: "Right pre sciatic L.N."
- P: "Left pre sciatic L.N."
- Q: "Pre sacral L.N."
- R: "Left ureter"
- S: "Right ureter"

CLINICAL INFORMATION:

Pre-op Dx: Bladder cancer

Post-op Dx: _

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Right ureter f/s". It consists of a segment of ureter measuring 0.4 cm in length x 0.6 cm in diameter. The specimen is entirely submitted for frozen section diagnosis in AFS.

B: The specimen is received fresh from the O.R. and labeled "Left ureter f/s". It consists of a segment of ureter measuring 0.4 cm in length x 0.6 cm in diameter. The specimen is entirely submitted for frozen section diagnosis in BFS.

C: The specimen is received fresh from the O.R. and labeled "Urethral margin". It consists of a tan soft tissue segment measuring 1.2 x 0.4 x 0.4 cm. The specimen is entirely submitted for frozen section diagnosis in CFS.

D: The specimen is received fresh from the O.R. and labeled "Uterus, cervix, ovaries, bladder". It consists of a urinary bladder, uterus, cervix and bilateral ovaries and fallopian tubes measuring overall 25 x 20 x 2.7 cm. The attached peritoneum measures 15 x 9 x 0.1 cm, which is smooth and glistening. The perivesical resection margin is inked black. The urinary bladder is opened anteriorly to reveal two lesions, one ulcerative and the other papillary and exophytic. The ulcer ulcerative lesion is located on the right lateral wall 2 cm above and lateral to the right ureterovesical junction. The papillary lesion measures 4 x 3 x 1 cm and partially surrounds the mouth of a diverticulum in the dome. No definitive gross invasion of the bladder wall is seen by either of the two lesions. The diverticulum measures 4 x 2 x 1 cm and is lined by flat normal appearing mucosa. The remaining mucosa of the urinary bladder is unremarkable. Bilateral ureterovesical junctions are identified and are uninvolved by tumor. The attached right ureter measures 7 cm in length x 0.5 cm in diameter and the left ureter measures 6 cm in length x 0.5 cm in diameter. Both are unremarkable. The uterus measures 10 x 5 x 2.7 cm and is covered by unremarkable serosa. The cervix measures 2.5 cm in length x 3 cm in diameter. The exocervix is covered by smooth and glistening mucosa. The right ovary measures 3.5 x 1.5 x 0.7 cm. The right fallopian tube measures 7 cm in length x 0.5 cm in diameter. Both appear normal. The left ovary measures 4 x 1.5 x 0.8 cm. The left fallopian tube measures 9 cm in length x 0.5 cm in diameter. A paratubal cyst is identified on the left fallopian tube measuring 1.5 x 0.5 x 0.5 cm. The cervix and uterus are bivalved to reveal a sessile polypoid lesion on the posterior endometrial wall measuring 1.2 x 1 x 0.4

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

cm. The endometrial cavity measures 3 x 2 cm. The endometrium measures 0.1 cm. The myometrium measures 1.5 to 2 cm in full thickness. The endocervical canal measures 2.4 cm in length x 0.5 cm in diameter. Its mucosal lining is unremarkable. Representative sections are submitted in 22 cassettes.

E: The specimen is received in formalin and labeled "Right common iliac lymph node". It consists of pieces of tan soft tissue measuring in aggregate 3 x 2 x 0.4 cm. The specimen is entirely submitted in three cassettes.

F: The specimen is received in formalin and labeled "Left para aortic L.N.". It consists of a tan soft tissue segment measuring 2.5 x 1 x 0.8 cm. The specimen is entirely submitted in three cassettes.

G: The specimen is received in formalin and labeled "Right para caval L.N.". It consists of multiple tan soft tissue fragments measuring in aggregate 3.5 x 1 x 0.4 cm. The specimen is entirely submitted in four cassettes.

H: The specimen is received in formalin and labeled "Left common iliac L.N.". It consists of multiple tan soft tissue fragments measuring in aggregate 2.5 x 1.5 x 0.4 cm. The specimen is entirely submitted in three cassettes.

I: The specimen is received in formalin and labeled "Right L.N. of cloquet". It consists of multiple tan fibroadipose tissue fragments measuring in aggregate 1.5 x 1 x 0.4 cm. The specimen is entirely submitted in two cassettes.

J: The specimen is received in formalin and labeled "Right external iliac L.N.". It consists of multiple tan fibroadipose tissue fragments measuring in aggregate 4.5 x 2 x 0.4 cm. The specimen is entirely submitted in five cassettes.

K: The specimen is received in formalin and labeled "Right obturator hypogastric L.N.". It consists of multiple tan-yellow fibroadipose tissue fragments measuring in aggregate 3.5 x 1.5 x 0.4 cm. The specimen is entirely submitted in four cassettes.

L: The specimen is received in formalin and labeled "Left external iliac L.N.". It consists of tan fibroadipose tissue fragments measuring in aggregate 4 x 1.5 x 0.4 cm. The specimen is entirely submitted in five cassettes.

M: The specimen is received in formalin and labeled "Left L.N. of cloquet". It consists of a piece of tan soft tissue measuring 1.8 x 1.5 x 0.2 cm. The specimen is entirely submitted in two cassettes.

N: The specimen is received in formalin and labeled "Left obturator/hypogastric L.N.". It consists of multiple tan-yellow fibroadipose tissue fragments measuring in aggregate 2 x 1.5 x 0.4 cm. The specimen is entirely submitted in four cassettes.

O: The specimen is received in formalin and labeled "Right pre sciatic L.N.". It consists of multiple tan soft tissue fragments measuring in aggregate 0.8 x 0.4 x 0.2 cm. The specimen is entirely submitted in two cassettes.

P: The specimen is received in formalin and labeled "Left pre sciatic L.N.". It consists of multiple tan soft tissue fragments measuring in aggregate 0.8 x 0.8 x 0.4 cm. The specimen is entirely submitted in two cassettes.

Q: The specimen is received in formalin and labeled "Pre sacral L.N.". It consists of a piece of tan soft tissue measuring 4 x 0.8 x 0.2 cm. The specimen is entirely submitted in three cassettes.

R: The specimen is received in formalin and labeled "Left ureter". It consists of

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

a segment of ureter measuring 0.8 cm in length x 0.5 cm in diameter. The specimen is serially sectioned and entirely submitted in one cassette.

S: The specimen is received in formalin and labeled "Right ureter". It consists of a segment of ureter measuring 0.6 cm in length x 0.4 cm in diameter. The specimen is serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right ureter
BFS: frozen section, left ureter
CFS: frozen section, ureteral margin
D1: anterior urinary bladder wall
D2-5: ulcerative lesion
D6: right uterovesical junction
D7-10: papillary lesion around mouth with diverticulum at dome
D11: diverticulum
D12: posterior wall
D13: trigone and bladder neck margin
D14: left uterovesical junction
D15: left lateral wall
D16: anterior cervix
D17: posterior exocervix
D18: anterior endomyometrium
D19: posterior endomyometrium with polyp
D20: right ovary and fallopian tube
D21: left ovary and fallopian tube
D22: left para tubal cyst
E1-3: right common iliac lymph node - all embedded
F1-3: left para aortic lymph node - all embedded
G1-4: right para caval lymph node - all embedded
H1-3: left common iliac lymph node - all embedded
I1-2: right lymph node of Cloquet - all embedded
J1-5: right external iliac lymph node - all embedded
K1-4: right obturator hypogastric lymph node - all embedded
L1-3: left external iliac lymph node - all embedded
M1-2: left lymph node of Cloquet - all embedded
N1-4: left obturator/hypogastric lymph node - all embedded
O1-2: right pre sciatic lymph node - all embedded
P1-2: left pre sciatic lymph node - all embedded
Q1-3: pre sacral lymph node - all embedded
R: left ureter, serially sectioned - all embedded
S: right ureter, serially sectioned - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right ureter
- no high-grade atypia or tumor identified
BFS: Left ureter
- no high-grade atypia or tumor identified
CFS: Urethral margin
- no high-grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

A-C: See final microscopic-diagnoses.

D: Sections of the bladder show invasive poorly differentiated urothelial carcinoma of the right lateral wall (ulcerated lesion D2-5) and dome (papillary lesion (D7-10) associated with both flat and papillary processes. The tumor involves the lamina propria of the right lateral wall and the superficial muscularis propria (D10) of the dome. Individual cells range from moderate to markedly pleomorphic corresponding with grades 3 and 4/4. Urothelial carcinoma in situ is seen in sections from the right lateral wall (D3-5) in association with the invasive carcinoma. Sections of the non-neoplastic bladder mucosa show multifocal chronic inflammation with associated reactive urothelial changes. Resection margins are free of urothelial dysplasia and malignancy.

E-S: See final microscopic-diagnoses.

Source: NCI Genomic Data Commons file 874a5243-9bda-4e43-9860-c9d25bdee1e2 (TCGA-XF-AAMQ.6A895DCD-0417-4FC1-AE0C-CB72BE55E889.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).